Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7F3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7F3-01A (Primary Tumor).

[page 1 of 4]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Not Released

Surgical Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:
In Lab Date:
Report Date:

Patient:

MRN:

Encounter #:
Location:
Age/ Sex:

CLINICAL INFORMATION:
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:

A-D. Frozen section diagnosis: Soft tissue only.
Reported to:

GROSS DESCRIPTION:

A. Received fresh the specimen is labeled "left mid neurovascular margin" and consists of a 0.4 x 0.2 with 0.1 cm piece of pink-tan soft tissue. The specimen is entirely submitted for intraoperative consultation. Summary of sections: A1 FSC.

B. Received fresh the specimen is labeled "right anterior apical margin" and consists of a 0.4 x 0.3 x 0.2 cm piece of pink-tan soft tissue. The specimen is entirely submitted for intraoperative frozen section. Summary of sections: B1 FSC.

C. Received fresh, specimen is labeled "left posterior para-apical margin" and consists of a 0.3 x 0.2 x 0.1 cm piece of pink-tan soft tissue. The specimen is entirely submitted for intraoperative frozen section consultation. Summary of sections: C1 FSC.

D. Received fresh, the specimen is labeled "left mid posterior lateral" and consists of a circular 3 x 0.1 x 0.1 cm piece of pink-tan soft tissue. The specimen is entirely submitted for intraoperative frozen section consultation. Summary of sections: D1 FSC.

E. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 72.4 gram radical prostatectomy specimen including a 5 x 4.5 x 4 cm prostate, a 3 x

CCF= ICD-O-3
Adenocarcinoma, acinar 8140/3
Path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/26/13

[page 2 of 4]
1.5 x 1 cm left seminal vesicle, a to e 0.5 cm left vas deferens, a 2.5 x 1.5 x 1 cm right seminal vesicle, and a 2 x 0.5 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to E respectively. Level B is submitted for research. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted in alternate sections. Summary of sections:

E1-RSV and LSV, E2- anterior apex, E3-E4- posterior apex, E5-ARA, E6-additional ARA (no ink), E7-ARP, E8-ALA, E9-ALP, E10-CRA, E11-CRP, E12-CLA, E13-CLP, E14-E15-ERP, E16-E17-ELP, E18-R posterior base, E19-L posterior Base, E20-anterior base, E21-posterior base, E22- additional soft tissue from the left side.

F. Received fresh to the specimen is labeled "pelvic lymph nodes". It consists of a 4 x 3 x 1 cm aggregate of fibrofatty tissue lymph nodes. The specimen is entirely submitted. Summary of sections: F1-F5.

G. Received fresh specimen is labeled "anterior prostatic fat". He consist of a 3.5 x 2 x 1 cm aggregate of fibrofatty tissue. The specimen is entirely submitted. Summary of sections: G1.

DIAGNOSIS:

A. Prostate gland, left mid neurovascular margin (biopsy):
Adipose and fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.

B. Prostate gland, right inferior apical margin (biopsy):
Adipose and fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.

C. Prostate gland, left posterior apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.

D. Prostate gland, left mid posterior lateral (biopsy):
Fibromuscular tissue.
No prostatic glands or carcinoma identified.

E. Prostate gland and seminal vesicles (radical prostatectomy):

Dominant nodule

Prostatic adenocarcinoma, Gleason score 3+4=7,
bilateral, organ confined, located in the apex.

Secondary nodule(s)

Prostatic adenocarcinoma, Gleason score 3+3=6 with
tertiary Gleason pattern 4, bilateral, organ confined, located in
the anterior para-apical region.

Foci of prostatic adenocarcinoma, Gleason score 3+3=6,
unilateral, organ confined, located in the right
mid-gland

Seminal vesicles and all surgical margins are negative
for tumor.

Please see attached Pathological Staging Summary.

F. Lymph nodes, pelvic (excision):

[page 3 of 4]
Nineteen lymph nodes, negative for metastatic carcinoma
(0/19).

G Fat, anterior prostate (excision):
Mature fibroadipose tissue, negative for carcinoma.

SYNOPSIS:

Histologic Type: (conventional, not otherwise specified)	Adenocarcinoma
Tumor Quantitation: prostatic tissue involved by tumor: 5%	Primary Pattern: Grade 3 Secondary Pattern: Grade 4 Total Gleason Score: 7 Proportion (percent) of
Pathologic Staging (pTNM): node metastasis	pT2c: Bilateral disease pN0: No regional lymph
nodes examined: 19	Number of regional lymph
nodes involved: 0	Number of regional lymph
cannot be assessed	pMx: Distant metastasis
Margins: invasive carcinoma	Margins uninvolved by
Extraprostatic Extension:	Absent
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings: intraepithelial neoplasia (PIN)	High-grade prostatic
hyperplasia	Benign prostatic

** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

ICD9 Codes: A-G 185
Billing Codes: A-D, (Inpatient)
A-D, G
E;
F;
SNOMED:

Slides: A-2, B-2, C-2, D-2, E-22, F-5, G-1
Resulting Agency

Specimen Collected: Last Resulted:

Order Information Lab Collection Information, Order Information, Order Providers

[page 4 of 4]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 968a8448-a1ec-4367-916f-8730d2fd802f (TCGA-KC-A7F3.8878BDE3-634E-497C-AC4A-219E2F0B7153.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).